Somatic mutation profile of tumor specimen TCGA-AF-3914-01A (aliquot TCGA-AF-3914-01A-01W-1073-09) from TCGA case TCGA-AF-3914, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 39.5 years (14,426 days).
Specimen TCGA-AF-3914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b312eef2-bd4e-4020-82f9-f7d98737087e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-3914-11A (Solid Tissue Normal), aliquot TCGA-AF-3914-11A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc7075a6-6cea-4f18-8417-aae889c958f2

The open-access MAF lists 120 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 31, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 294/355 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 14/113 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 56/176 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.3139G>A p.V1047M | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV99221257; called by muse, mutect2, varscan2
- ACTN1 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1258108178, CM150761, COSV99517847; called by muse, mutect2, varscan2
- ADPRH | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 75/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100813312; called by muse, mutect2, varscan2
- AKAP1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as rs781062994, COSV58471596; called by muse, mutect2, varscan2
- ALPK1 | c.1221A>C p.E407D | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99454072; called by muse, mutect2, varscan2
- ARHGEF28 | c.1365C>G p.N455K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs759407440, COSV55246428; called by muse, mutect2
- BRD9 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51319182; called by muse, mutect2, varscan2
- BRMS1L | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99396655; called by muse, mutect2
- BTAF1 | c.4467G>T p.M1489I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99795317; called by muse, mutect2
- C8B | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100980769; called by muse, mutect2, varscan2
- C9orf43 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 101/708 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99928344; called by muse, mutect2, varscan2
- CCDC7 | c.2465A>G p.D822G | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs958862071, COSV100178305; called by muse, mutect2
- CDH23 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs563224115, COSV54923049; called by muse, mutect2
- CDH9 | c.500G>C p.S167T | Missense Mutation (SNP) | VAF 39/402 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.1); catalogued as COSV99144635; called by muse, mutect2
- CILP | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99973368; called by muse, mutect2
- CLVS2 | c.951A>C p.E317D | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.015); catalogued as COSV51565319, COSV99252742; called by muse, mutect2, varscan2
- COL6A6 | c.1379C>A p.S460* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | catalogued as COSV62016646, COSV62024531; called by muse, mutect2, varscan2
- CUX2 | c.4421G>A p.R1474Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs556464147, COSV55622976; called by muse, mutect2, varscan2
- DCC | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV100500001; called by muse, mutect2, varscan2
- DMXL2 | c.8261G>A p.G2754E | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV51848756, COSV99196356; called by muse, mutect2
- DNAH3 | c.2614C>A p.L872M | Missense Mutation (SNP) | VAF 27/568 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99767371; called by muse, mutect2
- FCRL6 | c.1077G>C p.V359= | Splice Region (SNP) | VAF 12/426 reads (3%) | catalogued as COSV100220187, COSV58942755; called by muse, mutect2
- FSTL5 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100055479, COSV60187156, COSV60193080; called by muse, mutect2, varscan2
- GJA8 | c.1063A>G p.R355G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1553242982, COSV99569370; called by muse, mutect2, varscan2
- GPLD1 | c.1595T>C p.I532T | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs754141804, COSV100015314; called by muse, mutect2, varscan2
- GRB7 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 21/447 reads (5%) | catalogued as rs1249376854, COSV100485345, COSV100485492; called by muse, mutect2
- H3C6 | c.170A>T p.K57M | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as COSV64519916; called by muse, mutect2
- HYDIN | c.2563A>G p.N855D | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769442695, COSV100377911; called by muse, mutect2, varscan2
- IL1RL1 | c.1086A>C p.R362S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99294059; called by muse, mutect2, varscan2
- IL7R | c.667A>C p.S223R | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100286271, COSV57406413; called by muse, mutect2
- KCNA4 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV60250361; called by muse, mutect2
- KLHDC2 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs765114426, COSV53586421; called by muse, mutect2, varscan2
- KRT6A | c.1453A>G p.N485D | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs1157714217, COSV58103401, COSV58106640; called by muse, mutect2, varscan2
- LRRIQ1 | c.2247T>G p.F749L | Missense Mutation (SNP) | VAF 82/738 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV67824822; called by muse, mutect2, varscan2
- LRRK2 | c.839-1G>A p.X280_splice | Splice Site (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100110154; called by muse, mutect2
- LRRN3 | c.1347A>T p.E449D | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV100070458; called by muse, mutect2, varscan2
- MAGED1 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as COSV100431575; called by muse, mutect2, varscan2
- MED17 | c.1120A>G p.N374D | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99315969; called by muse, mutect2
- MXRA5 | c.3740C>T p.T1247I | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV54242608; called by muse, mutect2
- MYO10 | c.4439A>G p.K1480R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99945320; called by muse, mutect2, varscan2
- NEO1 | c.923G>C p.S308T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV99982010; called by muse, mutect2, varscan2
- NFIX | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100666411, COSV62175630; called by muse, mutect2
- NOTCH2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as rs782066959, COSV56690300; called by muse, mutect2, varscan2
- NPY1R | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.871); catalogued as COSV56715663, COSV99649064; called by muse, mutect2, varscan2
- OBSCN | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs376879212; called by muse, mutect2, varscan2
- OGFOD1 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100272990, COSV100273022; called by muse, mutect2, varscan2
- OR13C3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 47/451 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs369932733; called by muse, mutect2, varscan2
- OR52B4 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68768533; called by muse, mutect2, varscan2
- OR5R1 | c.9A>C p.E3D | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56572440, COSV56573131; called by muse, mutect2, varscan2
- OR6K3 | c.823T>G p.L275V (on ENST00000368146; = p.L259V on NM_001005327.2) | Missense Mutation (SNP) | VAF 108/382 reads (28%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- PCDH11X | c.3304A>T p.N1102Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV53438500, COSV53472805; called by muse, mutect2, varscan2
- PCDHB6 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV50700643; called by muse, mutect2, varscan2
- PCDHB8 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as COSV50753660, COSV99176931; called by muse, mutect2
- PDGFRB | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940592; called by muse, mutect2
- PPP4R3A | c.2122G>A p.D708N (on ENST00000554943 / NM_001366432.1; = p.D695N on NM_001284280.1) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV100466045; called by muse, mutect2, varscan2
- PTPRO | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs755731862, COSV55506898, COSV99840497; called by muse, mutect2
- PXDNL | c.1449A>C p.Q483H | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV62476526; called by muse, mutect2, varscan2
- PZP | c.3676C>A p.Q1226K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.506); catalogued as COSV99737688; called by muse, mutect2
- RAI14 | c.2179T>C p.S727P | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99463045; called by muse, mutect2
- REV3L | c.4655C>T p.S1552F | Missense Mutation (SNP) | VAF 91/451 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100725169; called by muse, mutect2, varscan2
- RIMS1 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53486804, COSV99326825; called by muse, mutect2
- RNF165 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs368560170, COSV99491356; called by muse, mutect2, varscan2
- SCAF1 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100862150; called by muse, mutect2, varscan2
- SCN5A | c.4057G>A p.V1353M (on ENST00000333535 / NM_198056.3; = p.V1352M on NM_000335.5) | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs199473233, CM100708, COSV61114948; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SERPINA7 | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.351); catalogued as COSV59664608, COSV59666098; called by muse, mutect2, varscan2
- SPART | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748475972, COSV62088990; called by muse, mutect2
- SPEF2 | c.5372A>C p.K1791T | Missense Mutation (SNP) | VAF 98/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs546674187, COSV100289482, COSV57426909, COSV57427611; called by muse, mutect2, varscan2
- SPHKAP | c.699T>G p.D233E | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60867477, COSV60882180; called by muse, mutect2, varscan2
- TARBP2 | c.637G>A p.A213T (on ENST00000266987 / NM_134323.2; = p.A192T on NM_004178.4) | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57198909; called by muse, mutect2, varscan2
- TGFB2 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV100860129; called by muse, mutect2, varscan2
- TLL1 | c.1563A>C p.E521D | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99286716; called by muse, mutect2
- TTN | c.8111T>G p.V2704G (on ENST00000591111; = p.V2658G on NM_003319.4) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | PolyPhen probably damaging (0.998); catalogued as COSV59864255; called by muse, mutect2, varscan2
- VAT1L | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs373317393, COSV100213472; called by muse, mutect2, varscan2
- VSTM2A | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56492364; called by mutect2, varscan2
- VWF | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 137/177 reads (77%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99779024; called by muse, mutect2, varscan2
- ZNF33A | c.1867C>G p.L623V (on ENST00000458705 / NM_006974.3; = p.L624V on NM_006954.2) | Missense Mutation (SNP) | VAF 38/576 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100275790; called by muse, mutect2
- ZNF382 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs760253473, COSV99497789; called by muse, mutect2, varscan2
- ZNF470 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.088); catalogued as COSV100401229; called by muse, mutect2
- ZNF500 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV99556316; called by muse, mutect2
- ZNF800 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.665); catalogued as rs1396505654, COSV99757901; called by muse, mutect2
- OR8G2P | c.127T>G p.L43V | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2
- PXK | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.04); called by muse, mutect2
- RBP3 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- STK33 | c.183del p.E62Kfs*8 | Frame Shift Del (DEL) | VAF 20/204 reads (10%) | called by mutect2, pindel
- ZFHX4 | c.6889dup p.R2297Kfs*5 | Frame Shift Ins (INS) | VAF 50/293 reads (17%) | called by mutect2, pindel, varscan2
- ACOX2 | c.795G>A p.E265= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV100250158; called by muse, mutect2
- ADCY9 | c.3648G>A p.L1216= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as rs1358144438, COSV53570724, COSV53573113; called by muse, mutect2, varscan2
- ARHGAP44 | c.1878G>A p.P626= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs769221429, COSV52392262, COSV99310670; called by muse, mutect2, varscan2
- BMPER | c.1311C>T p.T437= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as rs760041868, COSV51823310; called by muse, mutect2, varscan2
- CACNA1B | c.5736T>C p.L1912= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs373683016; called by muse, mutect2, varscan2
- CLEC16A | c.996G>A p.S332= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs200791178, COSV68497584; called by muse, mutect2, varscan2
- COL6A6 | c.5424C>T p.H1808= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1013008709, COSV62016661; called by muse, mutect2, varscan2
- CPNE4 | c.1086G>A p.G362= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1241609068, COSV101456690; called by muse, mutect2, varscan2
- CYP24A1 | c.774G>A p.E258= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as COSV99398300; called by muse, mutect2
- DCDC1 | c.4185C>T p.C1395= (on ENST00000597505 / NM_001367979.1; = p.C502= on NM_020869.3) | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV57997239; called by muse, mutect2, varscan2
- DCLK1 | c.531A>C p.R177= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV99711131; called by muse, mutect2, varscan2
- FLT3 | c.2646C>T p.F882= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV99608744; called by muse, mutect2, varscan2
- IKZF3 | c.768G>A p.L256= | Silent (SNP) | VAF 30/1135 reads (3%) | catalogued as COSV99499666; called by muse, mutect2
- KLHL25 | c.1725T>C p.L575= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100563577; called by muse, mutect2
- LRIG1 | c.2919G>A p.E973= | Silent (SNP) | VAF 24/400 reads (6%) | catalogued as rs914535127, COSV99833732; called by muse, mutect2
- MAP1B | c.6216C>T p.S2072= | Silent (SNP) | VAF 40/764 reads (5%) | catalogued as COSV99702366; called by muse, mutect2
- MYO16 | c.666A>T p.G222= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV99193890; called by muse, mutect2, varscan2
- NPFFR2 | c.117C>T p.R39= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV58148681; called by muse, mutect2, varscan2
- OSGEP | c.315G>A p.V105= | Silent (SNP) | VAF 70/214 reads (33%) | catalogued as COSV99247996; called by muse, mutect2, varscan2
- PEG3 | c.789C>T p.D263= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs142177720, COSV55627105; called by muse, mutect2, varscan2
- RGS3 | c.421C>T p.L141= (on ENST00000350696 / NM_001282923.2; = p.L29= on NM_017790.4) | Silent (SNP) | VAF 8/259 reads (3%) | catalogued as rs1157265340, COSV100465160, COSV58286144; called by muse, mutect2
- RIMS1 | c.211A>C p.R71= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as rs980106766, COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2, varscan2
- RPS3 | c.195G>A p.R65= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV53704049; called by muse, mutect2, varscan2
- SFXN2 | c.546C>T p.A182= | Silent (SNP) | VAF 27/197 reads (14%) | catalogued as rs755720291, COSV64013019; called by muse, mutect2, varscan2
- SPATA31D1 | c.2421T>C p.T807= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV61192267; called by muse, mutect2, varscan2
- TMEM132D | c.1809A>G p.Q603= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV67160830, COSV67161729; called by muse, mutect2
- TNFSF11 | c.492T>G p.P164= | Silent (SNP) | VAF 78/307 reads (25%) | catalogued as COSV53477418, COSV99520509; called by muse, mutect2, varscan2
- VEZF1 | c.708T>G p.V236= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99365714; called by muse, mutect2
- WSCD1 | c.1092C>T p.N364= | Silent (SNP) | VAF 34/541 reads (6%) | catalogued as COSV100496564; called by muse, mutect2
- ZFPM2 | c.2481C>T p.D827= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1286201473, COSV65872371; called by muse, mutect2, varscan2
- ZNF540 | c.1795A>C p.R599= | Silent (SNP) | VAF 104/311 reads (33%) | catalogued as COSV100329675, COSV57109044; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20113A>C | Intron (SNP) | VAF 9/62 reads (15%) | catalogued as rs1378358702, COSV67439789, COSV67444912; called by muse, mutect2, varscan2
